Somatic mutation profile of tumor specimen MP2PRT-PASGWC-TBP1-A (aliquot MP2PRT-PASGWC-TBP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PASGWC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (848 days).
Specimen MP2PRT-PASGWC-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64f53d32-c50c-4843-aaa1-798011164d70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASGWC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASGWC-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f61988f-8c2d-4276-bb97-31ae24c2a7d4

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 41/545 reads (8%) | catalogued as rs373221034, COSV60102332; ClinVar: pathogenic; called by muse, mutect2
- RP1L1 | c.2492C>T p.T831M | Missense Mutation (SNP) | VAF 139/754 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs543094284, COSV66754112; called by muse, mutect2, varscan2
- SLC22A25 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 75/357 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs368828937; called by muse, mutect2, varscan2
- UBE2D3 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 61/358 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV57662060; called by muse, mutect2, varscan2
- PTPRT | c.477T>A p.H159Q | Missense Mutation (SNP) | VAF 87/230 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- GRHL2 | c.1794C>T p.I598= | Silent (SNP) | VAF 104/486 reads (21%) | catalogued as rs770078441; called by muse, mutect2, varscan2
- TMEM255B | c.444C>T p.D148= | Silent (SNP) | VAF 101/269 reads (38%) | catalogued as rs201537526; called by muse, mutect2, varscan2
